Somatic mutation profile of tumor specimen TCGA-BR-4280-01A (aliquot TCGA-BR-4280-01A-01D-1126-08) from TCGA case TCGA-BR-4280, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 78.1 years (28,515 days).
Specimen TCGA-BR-4280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6ec66ad-f2ad-4010-a81c-6ef5fc30de03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4280-11A (Solid Tissue Normal), aliquot TCGA-BR-4280-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d43b8474-202e-4a34-a76e-4a6b990f0a4b

The open-access MAF lists 832 somatic variants for this specimen: 658 protein-altering or splice-affecting, 155 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 426, Frame Shift Del 159, Silent 155, Frame Shift Ins 33, Nonsense Mutation 19, Intron 8, Splice Site 7, Splice Region 7, 3'Flank 4, In Frame Del 4, 3'UTR 3, Translation Start Site 2.

Variants (750 of 832; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.2162dup p.S723Ifs*27 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs1554294674; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL1A2 | c.3269G>A p.G1090D | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs267606742, CM091167, COSV51956350; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.2203C>T p.R735* | Nonsense Mutation (SNP) | VAF 61/166 reads (37%) | catalogued as rs121917901, CM980626; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- MMUT | c.29dup p.L10Ffs*39 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | catalogued as rs1437477079; ClinVar: pathogenic; called by mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 98/376 reads (26%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 43/110 reads (39%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- ABCC11 | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV62322580; called by muse, mutect2, varscan2
- ABCC9 | c.722del p.K241Sfs*5 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | catalogued as rs1413468210; called by mutect2, pindel, varscan2
- ABHD1 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53205586; called by muse, mutect2, varscan2
- ACSS1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs780332877, COSV60219277; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 85/117 reads (73%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS14 | c.1025A>G p.Q342R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV64601332; called by muse, mutect2, varscan2
- ADAMTS16 | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1344523569, COSV99943602; called by muse, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 45/110 reads (41%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS5 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV53177982; called by muse, mutect2, varscan2
- ADARB1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as rs1298394382, COSV62343654; called by muse, mutect2, varscan2
- ADCY7 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV54265917; called by mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADGRB1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60093232; called by muse, mutect2
- ADGRG4 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54953891; called by muse, mutect2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | catalogued as rs761350619; called by mutect2, varscan2
- ADSS1 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58273042; called by muse, mutect2, varscan2
- AFM | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1305597859, COSV56919777; called by muse, mutect2, varscan2
- AIF1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV61962329; called by muse, mutect2, varscan2
- AJM1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56032523, COSV99915909; called by muse, mutect2, varscan2
- AKAP4 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62074198; called by muse, mutect2, varscan2
- AKAP4 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as COSV62074204; called by muse, mutect2, varscan2
- AKAP6 | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55211101; called by muse, mutect2, varscan2
- AKAP9 | c.8321T>C p.L2774S (on ENST00000359028; = p.L2750S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as COSV62343573; called by muse, mutect2, varscan2
- AKNA | c.2270T>A p.V757D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56312170; called by muse, mutect2, varscan2
- ALG3 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.098); catalogued as rs778696645, COSV56611058; called by mutect2, varscan2
- ALPK2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64492131; called by muse, mutect2, varscan2
- AMER1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs769608759, COSV57658768, COSV57659074; called by muse, mutect2, varscan2
- AMIGO3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1375960532, COSV57538247; called by muse, mutect2, varscan2
- ANKRD42 | c.1088A>C p.D363A | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV52615441; called by muse, mutect2, varscan2
- ANO8 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs776134539, COSV50175460; called by muse, mutect2, varscan2
- ANOS1 | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.915); catalogued as COSV52918391; called by muse, varscan2
- ANXA8 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1220680586; called by muse, mutect2, varscan2
- AP3B2 | c.2126G>T p.S709I | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55608638; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP2 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.803); catalogued as rs775209531, COSV58285497; called by muse, mutect2, varscan2
- ARFGEF1 | c.5389A>G p.K1797E | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.146); catalogued as COSV51583012; called by muse, mutect2, varscan2
- ARFGEF2 | c.1643A>C p.E548A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV64211795; called by muse, mutect2
- ARHGAP8 | c.79+2T>C p.X27_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61232722; called by muse, mutect2, varscan2
- ARHGEF18 | c.1226G>A p.G409D (on ENST00000359920 / NM_001130955.2; = p.G305D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV60468933; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 54/119 reads (45%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC4 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs750563454, COSV53464285; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs149330911, COSV63437569; called by muse, mutect2, varscan2
- ARSL | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66965101; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs761154268; called by mutect2, varscan2
- ASXL3 | c.2168C>A p.P723H | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52463282; called by muse, mutect2, varscan2
- ATF7IP | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV53769106; called by muse, mutect2, varscan2
- ATG4C | c.468del p.K156Nfs*23 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as rs1272625060, COSV58608782; called by mutect2, pindel, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs1555143544, COSV63112070; called by mutect2, pindel, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATXN7 | c.1765T>C p.C589R | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV55749723; called by muse, mutect2, varscan2
- AZIN2 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53856911; called by muse, mutect2, varscan2
- B4GALT2 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99356713; called by muse, mutect2, varscan2
- BARD1 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV53610944; called by muse, mutect2, varscan2
- BBS7 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV52655722; called by muse, mutect2, varscan2
- BEST3 | c.1332dup p.R445Qfs*58 | Frame Shift Ins (INS) | VAF 24/69 reads (35%) | catalogued as rs779566914; called by mutect2, varscan2
- BLM | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV61923474; called by muse, mutect2
- BMP8B | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV59593653; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 69/122 reads (57%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPTF | c.8276T>C p.L2759P | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58835346; called by muse, mutect2, varscan2
- BRINP2 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1293183034, COSV64176940, COSV64181324; called by muse, mutect2, varscan2
- BRSK1 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772613846, COSV58665860; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BTBD11 | c.2497G>A p.A833T (on ENST00000280758 / NM_001018072.2; = p.A370T on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs752845135, COSV55022125; called by muse, mutect2, varscan2
- BTBD3 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 133/458 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.412); catalogued as rs776639503, COSV54778795; called by muse, mutect2, varscan2
- C19orf47 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63508851; called by muse, mutect2, varscan2
- C19orf57 | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60967944; called by muse, mutect2, varscan2
- C9orf72 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV66154678; called by muse, mutect2, varscan2
- CABP7 | c.641T>C p.M214T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53362817; called by muse, mutect2, varscan2
- CACNA1E | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV100701529, COSV62390108; called by muse, mutect2, varscan2
- CAMK1D | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66613115; called by muse, mutect2, varscan2
- CAP2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1195287566, COSV57731352; called by muse, mutect2, varscan2
- CAPN15 | c.3228G>T p.E1076D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV54835269; called by muse, mutect2
- CASP8 | c.1252G>T p.G418* (on ENST00000432109 / NM_033355.3; = p.G435* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV51849259; called by muse, mutect2, varscan2
- CASS4 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV64386021, COSV64387872; called by muse, mutect2, varscan2
- CBY2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1399175372, COSV60117172; called by muse, mutect2
- CCBE1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67949676; called by muse, mutect2, varscan2
- CCDC114 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1423707988, COSV59556190; called by muse, mutect2, varscan2
- CCDC39 | c.1329A>C p.E443D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.103); catalogued as COSV56482193; called by muse, mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as rs781790231; called by mutect2, varscan2
- CCR2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/138 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV52748337; called by muse, mutect2, varscan2
- CDC45 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV54244610; called by muse, mutect2, varscan2
- CDH12 | c.1041A>C p.K347N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV66398431; called by muse, mutect2
- CDH20 | c.59T>C p.L20S | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV53008112; called by muse, mutect2, varscan2
- CDH20 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV53008123; called by muse, mutect2, varscan2
- CDH24 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.087); catalogued as rs1244911981, COSV57460165; called by muse, mutect2, varscan2
- CDH8 | c.421T>C p.W141R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54860984; called by muse, mutect2, varscan2
- CEMIP2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.081); catalogued as rs758933988, COSV65486696; called by muse, mutect2, varscan2
- CEP83 | c.804T>C p.A268= | Splice Region (SNP) | VAF 15/21 reads (71%) | catalogued as rs1333384162, COSV60407754; called by muse, mutect2, varscan2
- CEP85 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV53328799; called by muse, mutect2
- CES1 | c.920A>T p.D307V | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV62086533; called by muse, mutect2, varscan2
- CFAP47 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as rs1340321021, COSV52881153; called by muse, mutect2, varscan2
- CFAP70 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60282552, COSV60282913; called by muse, mutect2, varscan2
- CHD5 | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV52412415; called by muse, mutect2, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs748826986; called by mutect2, varscan2
- CHL1 | c.1723A>G p.N575D (on ENST00000397491 / NM_001253387.1; = p.N591D on NM_006614.4) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as rs1277475628, COSV56591007; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST1 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs976283351, COSV57323126; called by muse, mutect2, varscan2
- CHST10 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as rs764927277, COSV51804914; called by muse, mutect2, varscan2
- CIAO2A | c.290-1G>T p.X97_splice | Splice Site (SNP) | VAF 24/71 reads (34%) | catalogued as COSV55538208; called by muse, mutect2, varscan2
- CLEC18A | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1431509593, COSV55344522; called by muse, mutect2, varscan2
- CLGN | c.1522del p.T508Pfs*12 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | catalogued as rs1217577246; called by mutect2, pindel, varscan2
- CLPB | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53629105; called by muse, mutect2, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs752224729; called by mutect2, pindel, varscan2
- CNGA2 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 67/186 reads (36%) | catalogued as COSV61703983; called by muse, mutect2, varscan2
- CNTLN | c.525A>C p.E175D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as COSV52074651; called by muse, mutect2, varscan2
- CNTN1 | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61638672; called by muse, varscan2
- COL17A1 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV62226376; called by muse, mutect2
- COL4A2 | c.4275del p.G1426Efs*33 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV100847412, COSV64631360; called by mutect2, pindel, varscan2
- COMT | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs374506541; called by muse, mutect2, varscan2
- COQ8A | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as COSV62009050; called by muse, mutect2, varscan2
- CORIN | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56689849; called by muse, mutect2, varscan2
- CRACD | c.2278del p.Q760Sfs*69 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as COSV51720773; called by pindel, varscan2
- CRTAM | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs775161741, COSV57066614; called by muse, mutect2, varscan2
- CSMD3 | c.7957C>T p.R2653* (on ENST00000297405 / NM_001363185.1; = p.R2549* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | catalogued as rs1443055427, COSV52140719, COSV52280497; called by muse, mutect2, varscan2
- CTIF | c.1661T>G p.M554R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56482369; called by muse, mutect2, varscan2
- CTNND2 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.556); catalogued as COSV58864258, COSV58880491; called by muse, mutect2, varscan2
- CTU2 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs753781703, COSV56336072; called by muse, mutect2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP1A2 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100673957; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX42 | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV63789828; called by muse, mutect2, varscan2
- DDX54 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58372980; called by muse, mutect2, varscan2
- DIAPH2 | c.2825A>C p.K942T | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV61265994; called by muse, mutect2
- DLX6 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs530888638, COSV50293438; called by muse, mutect2, varscan2
- DMAP1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs201828316, COSV60000422; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.8774A>G p.H2925R (on ENST00000409039; = p.H2864R on NM_207437.3) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1205684113, COSV68991735; called by muse, mutect2, varscan2
- DNAJC7 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57268604; called by muse, mutect2, varscan2
- DNM1 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100360523, COSV57850563; called by muse, mutect2, varscan2
- DOCK1 | c.3584A>C p.N1195T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV54736448; called by muse, mutect2, varscan2
- DOCK3 | c.5499del p.G1834Vfs*63 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs34788750; called by mutect2, pindel, varscan2
- DOCK9 | c.3869G>A p.R1290H (on ENST00000376460 / NM_001366676.2; = p.R1291H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/365 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1334909665, COSV59625565, COSV59628424; called by muse, mutect2, varscan2
- DOP1B | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs775709171, COSV67692964; called by muse, mutect2, varscan2
- DPYSL4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58306825; called by muse, mutect2, varscan2
- DPYSL5 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554329592, COSV56510790; called by muse, mutect2, varscan2
- DRG2 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as rs1194164483, COSV56728133; called by muse, mutect2
- DRP2 | c.2272C>G p.H758D | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65810062; called by muse, mutect2, varscan2
- DSC2 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1342808624, COSV51863584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP21 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs376243334, COSV59134007; called by muse, mutect2, varscan2
- DUSP9 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61437908; called by muse, mutect2, varscan2
- DZIP1L | c.1712del p.P571Hfs*14 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs1220979198, COSV100551426; called by mutect2, pindel, varscan2
- ECH1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1255526502, COSV55489036; called by muse, mutect2, varscan2
- EDNRB | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.399); catalogued as COSV100527241; called by muse, mutect2, varscan2
- EDRF1 | c.2635del p.S879Afs*46 (on ENST00000356792 / NM_001202438.2; = p.S845Afs*46 on NM_015608.2) | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | catalogued as rs1388716596, COSV100523284; called by mutect2, pindel, varscan2
- EHBP1L1 | c.1241A>G p.E414G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV58572439; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 45/114 reads (39%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4G1 | c.3857C>T p.T1286M (on ENST00000346169 / NM_198241.3; = p.T1091M on NM_004953.5) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781371449, COSV59990358; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- ELF1 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs528981271, COSV53498350; called by muse, mutect2, varscan2
- EMD | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs782057378, COSV63962134; called by muse, mutect2, varscan2
- ENGASE | c.196del p.S66Pfs*53 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | catalogued as rs1256784410; called by mutect2, pindel, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | catalogued as rs756461692; called by mutect2, varscan2
- EREG | c.276C>T p.C92= | Splice Region (SNP) | VAF 37/98 reads (38%) | catalogued as rs1234894280, COSV55261167; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs753821453; called by mutect2, varscan2
- EXOC3L2 | c.2240del p.P747Lfs*49 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1261630384; called by mutect2, varscan2
- EXOC7 | c.312-2A>G p.X104_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV58741047; called by muse, mutect2, varscan2
- EXT1 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV65475098, COSV65477769; called by muse, mutect2
- EYA2 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1472320096, COSV57941454; called by muse, mutect2, varscan2
- F13A1 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277440557, COSV53557009; called by muse, mutect2
- FAM151B | c.756del p.K252Nfs*48 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs764889708; called by mutect2, pindel, varscan2
- FAM181A | c.1034del p.P345Hfs*35 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1297899717; called by mutect2, pindel, varscan2
- FAM193A | c.2849T>C p.M950T | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV61192958; called by muse, mutect2
- FAT3 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as rs370637047; called by muse, mutect2, varscan2
- FAT4 | c.13379C>A p.T4460K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV58680010, COSV58680473; called by muse, mutect2, varscan2
- FBN3 | c.3992G>A p.R1331Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs143347714; called by muse, mutect2, varscan2
- FBXO31 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs781136689, COSV61148490; called by muse, mutect2, varscan2
- FCRL4 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.105); catalogued as rs758734880, COSV54861582, COSV99620279; called by muse, mutect2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | catalogued as rs748969702; called by mutect2, varscan2
- FGGY | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as rs1308261823, COSV58031149; called by muse, varscan2
- FGL2 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1394142495, COSV50381001; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLCN | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53258719; called by muse, mutect2, varscan2
- FLNC | c.4991C>T p.T1664M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs780829334, COSV57950840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.2584G>A p.A862T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56105018; called by muse, mutect2, varscan2
- FMOD | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV61609876; called by muse, varscan2
- FOXO4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58575109; called by mutect2, varscan2
- FOXP1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as rs200629338; called by muse, mutect2, varscan2
- FRY | c.6979del p.T2327Pfs*55 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as COSV66568605; called by mutect2, pindel, varscan2
- FZR1 | c.444C>G p.Y148* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV58051303; called by mutect2, varscan2
- GALNT10 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs868139541, COSV51725163; called by muse, mutect2, varscan2
- GALNT6 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751562757, COSV62541984, COSV62543246; called by mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 17/31 reads (55%) | catalogued as rs758551787; called by mutect2, varscan2
- GBP2 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV65069083; called by muse, mutect2, varscan2
- GEN1 | c.2347A>G p.M783V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58056239; called by muse, mutect2, varscan2
- GFRA1 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV62604709; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs750227570; called by mutect2, varscan2
- GLMN | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.484); catalogued as rs751384639, COSV64860216; called by muse, mutect2, varscan2
- GLYCTK | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs377754882; called by muse, mutect2, varscan2
- GNL3L | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1387890381, COSV60575995; called by muse, mutect2, varscan2
- GNPTAB | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs201356176, COSV54778772; called by muse, mutect2, varscan2
- GOLT1A | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1181190296, COSV57643661; called by muse, mutect2, varscan2
- GP6 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV59977062; called by muse, mutect2, varscan2
- GPATCH8 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59194232; called by muse, mutect2, varscan2
- GPD1L | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs775043567, COSV56989654; called by muse, mutect2, varscan2
- GPR39 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV61422676; called by muse, mutect2, varscan2
- GREB1 | c.3269A>G p.D1090G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52184774; called by muse, mutect2, varscan2
- GRIN2A | c.1570T>G p.F524V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV58027758, COSV58028781; called by muse, mutect2, varscan2
- GSE1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53671264; called by muse, mutect2, varscan2
- GTF2F1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs1454074232, COSV66725529; called by muse, mutect2
- GUCY1A1 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56650940; called by muse, mutect2, varscan2
- GUCY2F | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV54300715; called by muse, mutect2, varscan2
- HARBI1 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs976983246, COSV58705878; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HCFC1 | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1433441527, COSV60071414; called by muse, mutect2, varscan2
- HCN3 | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV61360957, COSV61361395; called by muse, mutect2, varscan2
- HCN3 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs201531495, COSV61360960; called by muse, mutect2, varscan2
- HELQ | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV55024829; called by muse, mutect2, varscan2
- HERC1 | c.14353A>G p.N4785D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71247218; called by muse, mutect2, varscan2
- HLA-B | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1417633427, COSV69521036; called by muse, varscan2
- HNRNPAB | c.431del p.K144Rfs*5 | Frame Shift Del (DEL) | VAF 41/139 reads (29%) | catalogued as rs1561661581; called by mutect2, pindel, varscan2
- HPS3 | c.1503A>C p.K501N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV56053804; called by muse, mutect2, varscan2
- HSCB | c.452A>G p.E151G | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV53262236; called by muse, mutect2, varscan2
- HSPA1L | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.31); catalogued as rs762027845, COSV65148989; called by muse, mutect2, varscan2
- HTR5A | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1270474908, COSV55282263; called by muse, mutect2, varscan2
- HTT | c.3629C>A p.S1210Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV61860501; called by muse, mutect2, varscan2
- ICE2 | c.458del p.L153Cfs*27 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs1368340723; called by mutect2, pindel, varscan2
- IFT74 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV66286547; called by muse, mutect2, varscan2
- IGSF1 | c.2581A>G p.S861G | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63836971; called by muse, mutect2, varscan2
- IGSF10 | c.3688dup p.S1230Kfs*8 | Frame Shift Ins (INS) | VAF 44/125 reads (35%) | catalogued as rs36002001; called by mutect2, pindel, varscan2
- IGSF9 | c.1915del p.V639Yfs*114 (on ENST00000368094 / NM_001135050.2; = p.V623Yfs*114 on NM_020789.4) | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as COSV63641012; called by mutect2, pindel, varscan2
- IL17RE | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55967680; called by muse, mutect2, varscan2
- IL37 | c.100dup p.L34Pfs*31 | Frame Shift Ins (INS) | VAF 21/92 reads (23%) | catalogued as rs1335390716; called by mutect2, pindel, varscan2
- INPP4B | c.2621G>T p.R874L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV53720242, COSV53750965; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | catalogued as rs756928018; called by mutect2, varscan2
- IRX3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1200247563, COSV61668084; called by muse, mutect2
- ITGB4 | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1035224108, COSV52324556; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs760804226, COSV67347419, COSV67347964; called by muse, mutect2, varscan2
- ITSN2 | c.2368del p.T790Pfs*2 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as COSV100742542; called by mutect2, pindel, varscan2
- KANK4 | c.2546G>A p.C849Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308000804, COSV58092428; called by muse, mutect2, varscan2
- KCMF1 | c.887T>C p.L296S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV101301301; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNC2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV54367049; called by muse, mutect2, varscan2
- KCNN3 | c.2066C>T p.P689L (on ENST00000618040 / NM_001204087.1; = p.P674L on NM_002249.6) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679574; called by muse, mutect2, varscan2
- KCNN3 | c.1686A>T p.E562D (on ENST00000618040 / NM_001204087.1; = p.E547D on NM_002249.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV55215170; called by muse, mutect2, varscan2
- KCTD18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs543025211, COSV63344171; called by muse, mutect2, varscan2
- KDM2B | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65639724; called by muse, mutect2, varscan2
- KIF1A | c.2181G>T p.W727C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486746; called by muse, mutect2, varscan2
- KIF1A | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745504142, COSV57486774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF20A | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs375379655; called by muse, mutect2, varscan2
- KLHL13 | c.355T>C p.F119L | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53246653; called by muse, mutect2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as COSV55868319; called by mutect2, varscan2
- KMT2D | c.10646C>T p.A3549V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56429071; called by muse, mutect2, varscan2
- KPNA3 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as rs1189332677, COSV55504273; called by muse, mutect2, varscan2
- KRT10 | c.52G>T p.G18* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV54089288; called by muse, mutect2, varscan2
- KRT78 | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.077); catalogued as rs140505762, COSV100467768; called by muse, mutect2, varscan2
- KRTAP10-12 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs781816372; called by muse, mutect2
- KRTAP19-5 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.114); catalogued as rs555184478, COSV61858515; called by muse, mutect2, varscan2
- KSR1 | c.566G>A p.R189Q (on ENST00000644974 / NM_001367810.1; = p.R52Q on NM_014238.2) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs1199776213, COSV52028179; called by muse, mutect2, varscan2
- LARP1B | c.2361del p.K787Nfs*26 | Frame Shift Del (DEL) | VAF 36/89 reads (40%) | catalogued as rs758463950; called by mutect2, varscan2
- LATS1 | c.3245G>A p.R1082K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53589477; called by muse, mutect2, varscan2
- LDLRAD4 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63336117; called by muse, mutect2, varscan2
- LETM1 | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1327670408, COSV57099990; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXL3 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs1467895088, COSV51206963; called by muse, mutect2, varscan2
- LPCAT2 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs139462449, COSV100045320; called by muse, mutect2, varscan2
- LRBA | c.3682T>C p.C1228R | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV63953216; called by muse, mutect2, varscan2
- LRIF1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); catalogued as rs765992594, COSV63897132; called by muse, mutect2, varscan2
- LRP1 | c.6772A>G p.S2258G | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54508012; called by muse, mutect2, varscan2
- LRRC27 | c.1548del p.F516Lfs*22 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs761680254; called by mutect2, pindel, varscan2
- LTN1 | c.3941G>A p.G1314D | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63733523; called by muse, mutect2, varscan2
- LYST | c.7711C>T p.L2571F | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV67706054; called by muse, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEC1 | c.2438C>A p.P813H | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV53571155, COSV53571527; called by muse, mutect2, varscan2
- MAGEL2 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1273285142, COSV58566636; called by muse, mutect2, varscan2
- MAGI1 | c.4221del p.E1408Sfs*27 | Frame Shift Del (DEL) | VAF 35/101 reads (35%) | catalogued as rs1559874477; called by mutect2, pindel, varscan2
- MAP2K3 | c.710A>C p.N237T (on ENST00000342679 / NM_145109.3; = p.N208T on NM_002756.4) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100384768; called by muse, mutect2, varscan2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 28/113 reads (25%) | catalogued as rs748185381; called by mutect2, pindel, varscan2
- MCCC1 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55608080; called by muse, mutect2, varscan2
- MCM5 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369168183, COSV53345882; called by muse, mutect2, varscan2
- MCOLN1 | c.1628A>G p.Q543R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs766172784, COSV51174777; called by muse, mutect2, varscan2
- MCOLN2 | c.352A>C p.S118R | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV52294942; called by muse, mutect2, varscan2
- MEOX1 | c.739T>G p.S247A | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59355844, COSV59356604; called by muse, mutect2, varscan2
- METTL21A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV55881445, COSV55881568; called by muse, mutect2, varscan2
- MICAL2 | c.4033C>T p.P1345S | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56285406; called by muse, mutect2, varscan2
- MIDEAS | c.3126del p.K1042Nfs*51 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs1168947806; called by mutect2, pindel, varscan2
- MLKL | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs764970932, COSV58204777; called by muse, mutect2, varscan2
- MMEL1 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV56520316; called by muse, mutect2, varscan2
- MOCOS | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376215901; called by muse, mutect2, varscan2
- MOV10 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV62491128; called by muse, mutect2, varscan2
- MPO | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs1475169386, COSV56563060; called by muse, mutect2, varscan2
- MSANTD4 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs752235602, COSV57285627; called by muse, mutect2, varscan2
- MSTN | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53620788; called by muse, mutect2, varscan2
- MTREX | c.1855A>G p.N619D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57925260; called by muse, mutect2, varscan2
- MUSK | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs369023786; called by muse, mutect2, varscan2
- MVK | c.587T>A p.I196N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57331700; called by muse, mutect2, varscan2
- MYH10 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs371077973, COSV52598908; called by muse, mutect2, varscan2
- MYH6 | c.5071C>T p.R1691C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745747137, COSV62449460; called by muse, mutect2, varscan2
- MYO19 | c.1612T>C p.Y538H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190602642; called by muse, mutect2, varscan2
- MYO1D | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs201688080, COSV59010966; called by muse, mutect2, varscan2
- MYO3B | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753788691, COSV58695762; called by muse, mutect2, varscan2
- MYO7A | c.4175C>T p.A1392V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs753419655, COSV68684379; called by muse, mutect2, varscan2
- MYOM3 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs767696769, COSV58389451; called by muse, mutect2, varscan2
- NCAPD2 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59698832; called by muse, mutect2, varscan2
- NDRG2 | c.458C>T p.A153V (on ENST00000298687 / NM_001354570.1; = p.A139V on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs768988182, COSV53872241; called by muse, mutect2, varscan2
- NEFH | c.1827G>T p.K609N | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60216438; called by muse, varscan2
- NEXMIF | c.4433G>T p.G1478V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV50027205; called by muse, mutect2, varscan2
- NFRKB | c.932dup p.V312Gfs*2 (on ENST00000446488 / NM_001143835.2; = p.V337Gfs*2 on NM_006165.3) | Frame Shift Ins (INS) | VAF 52/138 reads (38%) | catalogued as rs149369172; called by mutect2, varscan2
- NISCH | c.3759G>T p.Q1253H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1469537712, COSV58734870; called by muse, mutect2, varscan2
- NLN | c.1678C>A p.L560I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.396); catalogued as rs1174217492, COSV66765573; called by muse, varscan2
- NLRP12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs781341758, COSV60743424, COSV60751214; called by muse, mutect2, varscan2
- NMNAT3 | c.493G>A p.V165M (on ENST00000296202 / NM_001320512.1; = p.V128M on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757954205, COSV56155565; called by muse, mutect2, varscan2
- NOTCH1 | c.1904-2A>G p.X635_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53043819; called by muse, mutect2, varscan2
- NPAP1 | c.2610A>C p.Q870H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV61505654, COSV61506061; called by muse, mutect2, varscan2
- NPC1L1 | c.3803G>A p.R1268H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs768530959, CM068039, COSV56924118; called by muse, mutect2, varscan2
- NPNT | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV59753137; called by muse, mutect2, varscan2
- NR1H2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs748179975, COSV53800558; called by muse, mutect2, varscan2
- NRBP2 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100589250; called by muse, mutect2, varscan2
- NSUN3 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58934904; called by muse, mutect2, varscan2
- NUMA1 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs1161432083, COSV61184725; called by muse, mutect2, varscan2
- NUP155 | c.3574T>A p.F1192I (on ENST00000231498 / NM_153485.3; = p.F1133I on NM_004298.4) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51529010; called by muse, mutect2, varscan2
- OGFOD3 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as rs372667205; called by muse, mutect2, varscan2
- OPN1SW | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs559471387, COSV50821206; called by muse, mutect2, varscan2
- OR10T2 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57780250, COSV57780869; called by muse, mutect2, varscan2
- OR11H12 | c.116A>C p.Q39P | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV73543572; called by muse, varscan2
- OR13C9 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52241514; called by muse, mutect2, varscan2
- OR13J1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1422988182, COSV65069563; called by muse, mutect2, varscan2
- OR2L13 | c.704A>G p.K235R | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV63547498, COSV63551722; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OR4Q3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59179991; called by muse, mutect2, varscan2
- OR5C1 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV65456036; called by muse, mutect2, varscan2
- OR5D18 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV61736806; called by muse, mutect2, varscan2
- OR7C1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.304); catalogued as COSV50183117; called by muse, mutect2, varscan2
- OTOP3 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV60912891; called by muse, mutect2, varscan2
- OTUD7B | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.316); catalogued as COSV64915861; called by muse, mutect2, varscan2
- P2RX6 | c.675del p.F225Lfs*40 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | catalogued as rs746330653; called by mutect2, pindel, varscan2
- P2RY10 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV50680951; called by muse, mutect2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 142/396 reads (36%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAPOLG | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs376377671; called by muse, mutect2, varscan2
- PAPSS1 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54488603; called by muse, mutect2, varscan2
- PCDH15 | c.5627A>G p.Q1876R | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1301403247, COSV57257450; called by muse, mutect2, varscan2
- PCDH15 | c.2896A>G p.R966G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV57292671; called by muse, mutect2, varscan2
- PCDH17 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64973368; called by muse, mutect2
- PCDH8 | c.23del p.G8Afs*48 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs1334380693; called by mutect2, pindel, varscan2
- PCDHA3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV65366265; called by muse, mutect2, varscan2
- PCK2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551184706, COSV53748018; called by muse, mutect2, varscan2
- PCLO | c.13259T>G p.F4420C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61628106; called by muse, mutect2, varscan2
- PCLO | c.9653G>A p.R3218H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as rs376658400, COSV61643055; called by muse, mutect2, varscan2
- PCNT | c.9106del p.M3036Wfs*14 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs1268347124; called by mutect2, pindel, varscan2
- PCNX3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV58419216; called by muse, mutect2, varscan2
- PDCD11 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771642253, COSV63933624; called by muse, mutect2, varscan2
- PDIK1L | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV65322504; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs759495724; called by mutect2, varscan2
- PDX1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs771445149, COSV66846899; called by muse, mutect2, varscan2
- PDZD2 | c.3436A>G p.T1146A | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56856122; called by muse, mutect2, varscan2
- PELI1 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62729863; called by muse, mutect2, varscan2
- PER2 | c.3382A>G p.I1128V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV54522955; called by muse, mutect2, varscan2
- PFDN4 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV65062842; called by muse, mutect2, varscan2
- PGLYRP1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.138); catalogued as COSV50516690; called by muse, mutect2, varscan2
- PHACTR1 | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV60664311; called by muse, mutect2, varscan2
- PHC2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs368911062; called by muse, mutect2, varscan2
- PHKG2 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV60311591; called by muse, mutect2, varscan2
- PIK3R6 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362142799, COSV61002575; called by muse, mutect2, varscan2
- PIMREG | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1207392299, COSV51470636; called by muse, mutect2, varscan2
- PITPNM2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs138122520; called by muse, mutect2, varscan2
- PKDCC | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV54306507; called by muse, mutect2, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PLA2G15 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV54718490; called by muse, mutect2, varscan2
- PLEKHG2 | c.2211_2212insT p.G738Wfs*21 | Frame Shift Ins (INS) | VAF 16/63 reads (25%) | catalogued as COSV99218410; called by mutect2, pindel, varscan2
- PMM1 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1316191643, COSV53447614; called by muse, mutect2, varscan2
- PNISR | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65079252; called by muse, mutect2
- PNMA8B | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as COSV66536296; called by muse, mutect2, varscan2
- PNPLA5 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs952620055, COSV53374535; called by muse, mutect2, varscan2
- POGLUT3 | c.833T>G p.I278S | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV60212337; called by muse, mutect2, varscan2
- POLA1 | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV66885408; called by muse, mutect2
- POLA1 | c.3158dup p.K1054Efs*8 | Frame Shift Ins (INS) | VAF 43/99 reads (43%) | catalogued as rs1159898227; called by mutect2, varscan2
- POLR1A | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV55691822; called by muse, mutect2, varscan2
- POTEF | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1032080960, COSV62539409; called by muse, mutect2, varscan2
- POU3F4 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64538602; called by muse, mutect2, varscan2
- PPIP5K2 | c.3713del p.N1238Tfs*35 (on ENST00000358359 / NM_001276277.3; = p.N1217Tfs*35 on NM_015216.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs201392612; called by mutect2, varscan2
- PPP2R2B | c.1190del p.G397Afs*31 (on ENST00000394409; = p.G463Afs*31 on NM_181674.2) | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | catalogued as rs767808084; called by mutect2, pindel, varscan2
- PPP2R5B | c.845T>G p.L282R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51210063; called by muse, mutect2, varscan2
- PRAMEF2 | c.866+1G>A p.X289_splice | Splice Site (SNP) | VAF 43/147 reads (29%) | catalogued as COSV53574538; called by muse, mutect2, varscan2
- PRB1 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.071); catalogued as rs768233652, COSV53703257; called by muse, mutect2, varscan2
- PRG4 | c.2024A>G p.N675S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63355259; called by muse, mutect2, varscan2
- PRRG3 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs200265801, COSV64850933; called by muse, mutect2, varscan2
- PRRT1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52997997; called by muse, mutect2, varscan2
- PSMC1 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54320599; called by muse, mutect2, varscan2
- PSTPIP2 | c.366A>G p.I122M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs1270895809, COSV68957758; called by muse, mutect2, varscan2
- PTGIS | c.1306del p.A436Rfs*31 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs778385193; called by mutect2, pindel, varscan2
- PTGIS | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148875055; called by muse, mutect2, varscan2
- PTOV1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377067186, COSV99681829; called by muse, mutect2, varscan2
- PTPDC1 | c.1849C>T p.Q617* (on ENST00000375360 / NM_177995.3; = p.Q669* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as rs1033382390, COSV56622685; called by muse, mutect2, varscan2
- PTPRF | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV63444273; called by muse, mutect2, varscan2
- PTPRG | c.2282A>G p.Y761C | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55636939; called by muse, mutect2, varscan2
- PTPRM | c.1515A>C p.E505D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV59854301; called by muse, mutect2, varscan2
- PTPRS | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.249); catalogued as COSV53616829; called by muse, mutect2, varscan2
- PXDN | c.3788C>G p.T1263S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53231516; called by muse, mutect2, varscan2
- RANBP2 | c.9527T>C p.L3176P | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51699438; called by muse, mutect2, varscan2
- RAPGEF5 | c.1273G>A p.A425T (on ENST00000401957 / NM_001367602.2; = p.A728T on NM_012294.5) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1199345171, COSV59781349; called by muse, mutect2, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 27/50 reads (54%) | catalogued as rs760908242; called by mutect2, varscan2
- RBBP8 | c.853T>G p.C285G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV59091901; called by mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1249861526, COSV56481867; called by muse, varscan2
- RERE | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs377669269; called by muse, varscan2
- RGL3 | c.1801A>C p.S601R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV66507639; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS3 | c.3034G>A p.V1012I (on ENST00000350696 / NM_001282923.2; = p.V731I on NM_130795.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs750641666, COSV59514911; called by mutect2, varscan2
- RNF111 | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV62085140; called by muse, mutect2, varscan2
- RNF6 | c.1778dup p.L593Ffs*4 | Frame Shift Ins (INS) | VAF 38/180 reads (21%) | catalogued as rs1199638878; called by mutect2, varscan2
- RNFT1 | c.1020del p.F340Lfs*4 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs1224280935; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 25/43 reads (58%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RUSC2 | c.3281A>G p.Q1094R | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV63428362; called by muse, mutect2, varscan2
- RXRA | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs1432522738, COSV62684075; called by muse, mutect2, varscan2
- RYR1 | c.12204G>T p.K4068N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62094632; called by muse, mutect2, varscan2
- SAMHD1 | c.1774T>G p.*592Gext*17 (on ENST00000262878 / NM_001363729.2; = p.*627Gext*17 on NM_015474.4) | Nonstop Mutation (SNP) | VAF 37/162 reads (23%) | catalogued as COSV53429176; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 53/149 reads (36%) | catalogued as rs765867975; called by mutect2, varscan2
- SBNO2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62319882; called by muse, mutect2
- SCD | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1451845439, COSV64853049; called by muse, mutect2, varscan2
- SCFD1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753170714, COSV61722253; called by muse, mutect2, varscan2
- SCN2A | c.5897C>T p.T1966M | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); catalogued as rs112098080, COSV51838196; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 30/60 reads (50%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SENP1 | c.1733A>C p.E578A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs1373405655, COSV50287419; called by muse, mutect2, varscan2
- SENP7 | c.404T>C p.L135S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.879); catalogued as COSV58610708; called by muse, mutect2, varscan2
- SEPTIN10 | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1241470246, COSV61779971; called by muse, mutect2, varscan2
- SERPINE3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1330299556, COSV68545174; called by muse, mutect2, varscan2
- SFXN2 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64012024; called by muse, mutect2, varscan2
- SGCA | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV56248943; called by muse, mutect2, varscan2
- SHANK1 | c.6346C>T p.R2116* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV53247587; called by muse, mutect2, varscan2
- SHANK1 | c.2420G>A p.S807N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV53247610; called by muse, mutect2, varscan2
- SHANK1 | c.2285T>C p.M762T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.591); catalogued as COSV53247631; called by muse, mutect2, varscan2
- SHPRH | c.4042C>T p.R1348C (on ENST00000275233 / NM_001042683.3; = p.R1352C on NM_173082.3) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs764452521, COSV51607874; called by muse, mutect2, varscan2
- SHROOM2 | c.4212del p.K1405Rfs*5 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1455440085; called by mutect2, varscan2
- SIGLEC6 | c.429C>A p.A143= | Splice Region (SNP) | VAF 30/91 reads (33%) | catalogued as rs1462904050, COSV58433062, COSV58436926; called by muse, mutect2, varscan2
- SLC12A4 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57928235; called by muse, mutect2, varscan2
- SLC13A2 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs141214124; called by muse, mutect2, varscan2
- SLC24A2 | c.1879C>T p.R627* | Nonsense Mutation (SNP) | VAF 67/156 reads (43%) | catalogued as COSV53862614; called by muse, mutect2, varscan2
- SLC25A12 | c.1397T>A p.V466D | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55532702; called by muse, mutect2, varscan2
- SLC39A5 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.221); catalogued as rs749619898, COSV57191394; called by muse, mutect2, varscan2
- SLC43A1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53558391; called by muse, mutect2, varscan2
- SLC7A14 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51578010; called by muse, mutect2, varscan2
- SLC9A7 | c.1405T>G p.L469V | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV60379470; called by muse, mutect2, varscan2
- SLCO1B3 | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV53935815; called by muse, mutect2, varscan2
- SLCO6A1 | c.1625del p.K542Rfs*13 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs866444182; called by mutect2, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMG6 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs752531928, COSV53969996; called by muse, mutect2
- SNX13 | c.1565C>A p.P522H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1357886886, COSV68064628; called by muse, mutect2, varscan2
- SPAM1 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV56142816; called by muse, mutect2, varscan2
- SPATA20 | c.1930A>G p.S644G (on ENST00000356488 / NM_001258372.1; = p.S660G on NM_022827.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs760237967, COSV50066331; called by muse, mutect2, varscan2
- SPDL1 | c.1771T>C p.Y591H | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.139); catalogued as COSV54667746; called by muse, mutect2, varscan2
- SPEF2 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56795982, COSV56801080; called by muse, mutect2, varscan2
- SPEF2 | c.4714A>G p.I1572V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57428509; called by muse, mutect2
- SPINDOC | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV53692026, COSV53692367; called by muse, mutect2, varscan2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | catalogued as rs567805129; called by mutect2, varscan2
- SQSTM1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs779807674, COSV62435358; called by muse, mutect2, varscan2
- SRSF7 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV57446798; called by muse, mutect2, varscan2
- STAB2 | c.5128A>G p.I1710V | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1168574961, COSV66337714; called by muse, mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | catalogued as rs746501298; called by mutect2, varscan2
- STPG2 | c.611del p.K204Rfs*6 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs778953320; called by mutect2, varscan2
- STX16 | c.304C>A p.L102I (on ENST00000371141 / NM_001001433.3; = p.L81I on NM_003763.6) | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56605030; called by muse, mutect2, varscan2
- SUGT1 | c.813A>G p.A271= (on ENST00000343788 / NM_001130912.3; = p.A239= on NM_006704.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as COSV59421647; called by muse, mutect2, varscan2
- SUSD1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.357); catalogued as COSV62582403; called by muse, mutect2, varscan2
- SYMPK | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs751061633, COSV55610901; called by muse, mutect2, varscan2
- TAAR1 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51588394; called by muse, mutect2, varscan2
- TAB2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1224456405, COSV53852096, COSV99644916; called by muse, mutect2, varscan2
- TADA2B | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as COSV53827088; called by muse, mutect2, varscan2
- TAOK1 | c.2547T>C p.I849= | Splice Region (SNP) | VAF 26/132 reads (20%) | catalogued as rs1567750688, COSV99914987; called by muse, mutect2, varscan2
- TAS2R38 | c.489dup p.S164* | Frame Shift Ins (INS) | VAF 23/70 reads (33%) | catalogued as rs1471160800; called by mutect2, pindel, varscan2
- TAS2R60 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60329927; called by muse, mutect2, varscan2
- TASOR2 | c.3688A>G p.T1230A | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1184590356, COSV60166963; called by muse, mutect2, varscan2
- TAT | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.152); catalogued as COSV100587613, COSV63532623; called by muse, mutect2, varscan2
- TBC1D10A | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471532118, COSV53163595; called by muse, varscan2
- TBC1D16 | c.1514A>G p.E505G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as COSV60476959, COSV60477720; called by muse, mutect2, varscan2
- TBC1D8 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs773935600, COSV65210014; called by muse, mutect2, varscan2
- TBCA | c.84del p.E29Rfs*12 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs1402309188; called by mutect2, pindel, varscan2
- TBPL2 | c.787A>G p.S263G | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV55972331; called by muse, mutect2, varscan2
- TBX10 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs200918283; called by muse, mutect2, varscan2
- TCF7L2 | c.1630G>A p.A544T (on ENST00000355995 / NM_001367943.1; = p.A521T on NM_030756.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.161); catalogued as rs758342453, COSV53339586; called by muse, mutect2, varscan2
- TCHH | c.3259C>T p.Q1087* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV64274117; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs763438715; called by mutect2, varscan2
- TCOF1 | c.3142C>T p.R1048W (on ENST00000377797 / NM_001135243.1; = p.R971W on NM_000356.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs764924499, COSV60347664; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 52/125 reads (42%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM1 | c.7115A>G p.H2372R | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV64429942; called by muse, mutect2, varscan2
- TENM1 | c.5495G>T p.W1832L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64429945; called by muse, mutect2, varscan2
- TEX10 | c.2482dup p.V828Gfs*28 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs767307629; called by mutect2, pindel, varscan2
- TGIF2LX | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV52213774, COSV52213806; called by muse, mutect2, varscan2
- TGM1 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1513233, COSV52862774; called by muse, mutect2, varscan2
- TGM5 | c.679G>A p.A227T (on ENST00000220420 / NM_201631.4; = p.A145T on NM_004245.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV55009698; called by muse, mutect2, varscan2
- THBS3 | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64249008; called by muse, mutect2, varscan2
- THUMPD2 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1558534781, COSV53187111; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TIMELESS | c.1733T>C p.M578T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57510600; called by muse, mutect2, varscan2
- TIMM44 | c.681C>T p.N227= | Splice Region (SNP) | VAF 19/63 reads (30%) | catalogued as rs761244845, COSV54491007, COSV54493859; called by muse, mutect2, varscan2
- TLE1 | c.1274del p.P425Lfs*3 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1394238712; called by mutect2, pindel, varscan2
- TLR9 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs747414072, COSV62345599, COSV62346408; called by muse, mutect2, varscan2
- TLR9 | c.1315del p.E439Rfs*47 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as rs1223235663; called by mutect2, pindel, varscan2
- TMCO3 | c.1707dup p.T570Hfs*114 | Frame Shift Ins (INS) | VAF 23/96 reads (24%) | catalogued as rs774763766; called by mutect2, pindel, varscan2
- TMCO5A | c.31del p.R11Efs*6 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as rs1463782356; called by mutect2, pindel, varscan2
- TMEM129 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV57558968; called by muse, mutect2, varscan2
- TMEM198 | c.1042G>T p.G348* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV54717221; called by muse, mutect2, varscan2
- TMEM268 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs373164511; called by muse, mutect2, varscan2
- TMEM98 | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as COSV55582556, COSV99912921; called by muse, mutect2, varscan2
- TMPRSS11F | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1308488868, COSV62465961; called by muse, mutect2, varscan2
- TMTC1 | c.2261A>G p.Y754C (on ENST00000539277 / NM_001193451.2; = p.Y646C on NM_175861.3) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs954762497, COSV55479422; called by muse, mutect2, varscan2
- TNKS | c.3008C>T p.A1003V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.017); catalogued as COSV60055514; called by muse, mutect2, varscan2
- TNN | c.1899G>C p.E633D | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53424743; called by muse, mutect2, varscan2
- TNS2 | c.1484del p.P495Rfs*25 (on ENST00000314250 / NM_170754.4; = p.P505Rfs*25 on NM_015319.2) | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs758743608; called by mutect2, pindel, varscan2
- TNS3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388960310, COSV60789674; called by muse, mutect2, varscan2
- TOB2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV59500793; called by muse, mutect2, varscan2
- TP53BP1 | c.2130del p.E711Nfs*12 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | catalogued as rs1375740992, COSV55498775; called by mutect2, pindel, varscan2
- TRIM32 | c.1285C>A p.L429I | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV57769838; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM65 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as rs374534100; called by muse, mutect2, varscan2
- TRIML2 | c.803T>G p.L268R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV58715554; called by muse, mutect2, varscan2
- TRIP12 | c.4639C>T p.R1547W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1320218400, COSV52262247; called by muse, varscan2
- TRMT2A | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV52813086; called by muse, mutect2, varscan2
- TRPC5 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53288291; called by muse, mutect2, varscan2
- TRPM5 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763058714, COSV50148622; called by muse, mutect2, varscan2
- TRRAP | c.7556C>T p.P2519L (on ENST00000359863 / NM_001244580.1; = p.P2501L on NM_003496.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs772886903, COSV62842701; called by muse, mutect2, varscan2
- TSNARE1 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1161556451, COSV56174122; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTLL7 | c.1948C>A p.H650N | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53083475, COSV53084463; called by muse, mutect2, varscan2
- TXLNB | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs963968093, COSV64443344; called by muse, mutect2, varscan2
- TYK2 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1242838061, COSV53386252; called by muse, mutect2, varscan2
- UBE4A | c.1115A>G p.Q372R (on ENST00000252108 / NM_001204077.2; = p.Q379R on NM_004788.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as COSV52803660; called by muse, mutect2, varscan2
- UNC13A | c.1688C>T p.T563M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1239657095, COSV53192997; called by muse, mutect2, varscan2
- UNK | c.1457dup p.S487* | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs751693027; called by mutect2, varscan2
- UPF2 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1177104668, COSV62659964; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.11449A>C p.T3817P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.522); catalogued as COSV56356606; called by muse, mutect2, varscan2
- USP22 | c.1444A>C p.S482R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV54946230, COSV54948354; called by muse, mutect2, varscan2
- UTP14A | c.1176C>G p.D392E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.888); catalogued as COSV64086654; called by muse, mutect2, varscan2
- VARS1 | c.786+2T>C p.X262_splice | Splice Site (SNP) | VAF 34/71 reads (48%) | catalogued as COSV65155067; called by muse, mutect2, varscan2
- VCAM1 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54118886; called by muse, mutect2, varscan2
- VCAN | c.2533A>G p.S845G | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV54102912, COSV54103950; called by muse, mutect2
- VCPIP1 | c.1900T>G p.F634V | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60046732; called by muse, mutect2, varscan2
- VPS33A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs765189927, COSV57356772; called by muse, mutect2, varscan2
- WDR13 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1556994008, COSV54330678; called by muse, mutect2, varscan2
- WDR33 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs767946537, COSV59247963; called by muse, mutect2, varscan2
- WDR43 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV56098372; called by muse, mutect2, varscan2
- WDR59 | c.2753A>G p.K918R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1452226879, COSV50934709; called by muse, mutect2, varscan2
- WDR62 | c.3465G>T p.K1155N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV54334053; called by muse, mutect2, varscan2
- WDR81 | c.3889A>G p.S1297G (on ENST00000409644 / NM_001163809.2; = p.S246G on NM_152348.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760440910, COSV58480949; called by muse, mutect2, varscan2
- WDR89 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs760393455, COSV50826391; called by muse, mutect2, varscan2
- WNT5A | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs866738848, COSV52836966; called by muse, mutect2, varscan2
- WWC3 | c.2104C>T p.L702= | Splice Region (SNP) | VAF 25/71 reads (35%) | catalogued as COSV66502619; called by muse, mutect2, varscan2
- XAGE3 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as COSV60569162; called by muse, mutect2, varscan2
- XIRP2 | c.9958G>A p.G3320R (on ENST00000628543; = p.G3495R on NM_152381.6) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307409351, COSV54693931; called by muse, mutect2, varscan2
- XK | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.535); catalogued as rs1413513552, COSV66120032, COSV66120212; called by muse, mutect2, varscan2
- XPO1 | c.1211C>A p.P404H | Missense Mutation (SNP) | VAF 112/337 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV68945596, COSV68946303, COSV68948144; called by muse, mutect2, varscan2
- YY2 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV63411159; called by muse, mutect2, varscan2
- ZBTB46 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV55508816; called by muse, mutect2, varscan2
- ZC3H12A | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs773544941, COSV100897734; called by muse, mutect2, varscan2
- ZDBF2 | c.5735C>T p.A1912V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV65624363; called by muse, mutect2, varscan2
- ZDBF2 | c.6578del p.K2193Rfs*57 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | catalogued as rs1420373273; called by mutect2, pindel, varscan2
- ZIM3 | c.1150del p.I384Sfs*49 | Frame Shift Del (DEL) | VAF 47/142 reads (33%) | catalogued as rs750173990; called by mutect2, pindel, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs751589999; called by mutect2, pindel
- ZNF205 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54620591; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF319 | c.542del p.P181Rfs*178 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs1229757997; called by mutect2, pindel, varscan2
- ZNF442 | c.1609A>T p.I537F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV54421164; called by muse, mutect2, varscan2
- ZNF461 | c.1149A>T p.K383N | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs976156031, COSV64453460, COSV64454507; called by muse, mutect2, varscan2
- ZNF506 | c.183del p.K61Nfs*3 | Frame Shift Del (DEL) | VAF 38/137 reads (28%) | catalogued as rs747582998; called by mutect2, pindel, varscan2
- ZNF543 | c.432del p.K145Sfs*6 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV100386962; called by mutect2, pindel, varscan2
- ZNF699 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV58025307; called by muse, mutect2, varscan2
- ZNF711 | c.2079del p.K693Nfs*3 | Frame Shift Del (DEL) | VAF 37/118 reads (31%) | catalogued as rs1264060719; called by mutect2, varscan2
- ZNF768 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53223585; called by muse, mutect2, varscan2
- ZNF821 | c.853C>T p.R285W (on ENST00000425432 / NM_001376297.1; = p.R243W on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777557917, COSV57987254; called by muse, mutect2, varscan2
- ZSCAN10 | c.26G>A p.R9Q (on ENST00000252463; = p.R64Q on NM_032805.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs530432636, COSV99374379; called by muse, varscan2
- ZSWIM3 | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54169133, COSV54170083; called by muse, mutect2, varscan2
- ADGRV1 | c.999del p.P334Hfs*9 | Frame Shift Del (DEL) | VAF 49/142 reads (35%) | called by mutect2, pindel, varscan2
- ADH1A | c.317dup p.N106Kfs*50 | Frame Shift Ins (INS) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- ARHGAP29 | c.1112del p.K371Sfs*12 | Frame Shift Del (DEL) | VAF 43/130 reads (33%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.1426dup p.I476Nfs*23 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | called by mutect2, varscan2
- BCHE | c.1760del p.N587Ifs*18 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- BCL9 | c.638_639del p.T213Rfs*17 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- BCL9L | c.4064del p.P1355Lfs*6 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- BCORL1 | c.918_921dup p.P308Sfs*113 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel
- BUB1B | c.897del p.M300Cfs*31 | Frame Shift Del (DEL) | VAF 47/155 reads (30%) | called by mutect2, pindel, varscan2
- CAMSAP2 | c.3643del p.T1215Lfs*23 (on ENST00000236925 / NM_001297707.2; = p.T1204Lfs*23 on NM_203459.3) | Frame Shift Del (DEL) | VAF 59/181 reads (33%) | called by mutect2, pindel, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 11/20 reads (55%) | called by mutect2, pindel, varscan2
- CDH24 | c.714del p.L239Cfs*7 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | called by mutect2, pindel, varscan2
- CHRNA5 | c.639del p.F213Lfs*9 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | called by mutect2, pindel, varscan2
- COL16A1 | c.4610dup p.G1538Rfs*42 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- CWC25 | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CWF19L2 | c.2261del p.L754Wfs*5 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- DMP1 | c.1104del p.D369Tfs*7 | Frame Shift Del (DEL) | VAF 80/240 reads (33%) | called by mutect2, pindel, varscan2
- DNAH5 | c.13458del p.F4486Lfs*7 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | called by mutect2, pindel, varscan2
- DRD1 | c.411del p.K138Rfs*6 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by mutect2, pindel, varscan2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- FBXO30 | c.1107del p.V370* | Frame Shift Del (DEL) | VAF 53/162 reads (33%) | called by mutect2, pindel, varscan2
- GGPS1 | c.735del p.K245Nfs*10 | Frame Shift Del (DEL) | VAF 35/85 reads (41%) | called by mutect2, pindel, varscan2
- GPM6A | c.738_740del p.C246_R247delinsW | In Frame Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- GPR55 | c.956del p.G319Afs*19 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- HCFC1 | c.389dup p.N130Kfs*29 | Frame Shift Ins (INS) | VAF 12/109 reads (11%) | called by mutect2, pindel, varscan2
- HRH3 | c.214_216del p.F72del | In Frame Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- IAPP | c.245_246dup p.P83Sfs*3 | Frame Shift Ins (INS) | VAF 26/90 reads (29%) | called by mutect2, varscan2
- IGHG4 | c.962T>A p.L321H | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- IGHM | c.625A>G p.N209D | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ITGAX | c.1444del p.H482Ifs*44 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- KIF1C | c.3017del p.P1006Lfs*82 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- KIF4B | c.2162_2164del p.Q721del | In Frame Del (DEL) | VAF 40/98 reads (41%) | called by pindel, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 33/104 reads (32%) | called by mutect2, varscan2
- KLHL28 | c.598del p.Y200Mfs*3 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- KLK1 | c.561del p.A188Pfs*6 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- LHX1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRP1 | c.2814del p.N939Tfs*41 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- LTBP2 | c.1017dup p.W340Lfs*35 | Frame Shift Ins (INS) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- MDN1 | c.7979_7982del p.E2660Vfs*3 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- MMP11 | c.1122del p.A375Hfs*9 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- MORC1 | c.1292del p.G431Dfs*18 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | called by mutect2, pindel, varscan2
- MOS | c.649dup p.I217Nfs*2 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- MRPL2 | c.873del p.M292* | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- MYO5B | c.1551dup p.K518Qfs*4 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- NDUFAF5 | c.1029del p.K343Nfs*30 | Frame Shift Del (DEL) | VAF 68/278 reads (24%) | called by mutect2, pindel, varscan2
- NFKB1 | c.1345del p.S449Vfs*7 (on ENST00000394820 / NM_001382627.1; = p.S450Vfs*7 on NM_003998.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 36/123 reads (29%) | called by mutect2, pindel, varscan2
- NR1D1 | c.636_637del p.K213Afs*6 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by pindel, varscan2
- OSBPL6 | c.2421del p.S808Lfs*31 | Frame Shift Del (DEL) | VAF 31/106 reads (29%) | called by mutect2, pindel, varscan2
- PCDH17 | c.2074del p.V692Yfs*4 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- PFKFB2 | c.798dup p.K267Efs*5 | Frame Shift Ins (INS) | VAF 32/129 reads (25%) | called by mutect2, pindel, varscan2
- PPP2R3A | c.826del p.T276Lfs*4 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- PRDM16 | c.1395del p.S466Afs*3 | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
- PZP | c.2007_2011del p.M669Ifs*6 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by pindel, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- RNF111 | c.2318del p.P773Hfs*44 | Frame Shift Del (DEL) | VAF 41/78 reads (53%) | called by mutect2, pindel, varscan2
- RNF148 | c.839dup p.H281Pfs*2 | Frame Shift Ins (INS) | VAF 35/110 reads (32%) | called by mutect2, pindel, varscan2
- ROM1 | c.1013del p.P338Hfs*60 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | called by mutect2, pindel, varscan2
- RUFY1 | c.2012_2014del p.F671del | In Frame Del (DEL) | VAF 19/51 reads (37%) | called by pindel, varscan2
- SCN3A | c.1706dup p.R570Kfs*4 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- SETD2 | c.4953dup p.T1652Yfs*14 | Frame Shift Ins (INS) | VAF 77/263 reads (29%) | called by mutect2, pindel, varscan2
- SETD3 | c.937del p.Y313Mfs*10 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- SHCBP1L | c.778del p.Y260Mfs*84 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel, varscan2
- SI | c.2025del p.F675Lfs*15 | Frame Shift Del (DEL) | VAF 45/144 reads (31%) | called by mutect2, pindel, varscan2
- SLC20A1 | c.824dup p.N276Efs*2 | Frame Shift Ins (INS) | VAF 37/122 reads (30%) | called by mutect2, varscan2
- SLC38A3 | c.63del p.L22Cfs*82 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- SMPD2 | c.805del p.L269Sfs*7 | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | called by mutect2, pindel, varscan2
- SORCS1 | c.837del p.H280Tfs*43 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- SPOUT1 | c.638del p.K213Rfs*3 | Frame Shift Del (DEL) | VAF 35/88 reads (40%) | called by mutect2, pindel, varscan2
- SUN5 | c.541del p.M181Wfs*5 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.435A>C p.E145D | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SYNE2 | c.17777del p.N5926Ifs*26 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- TGIF1 | c.578_579del p.L193Hfs*8 (on ENST00000330513 / NM_001374396.1; = p.L213Hfs*8 on NM_003244.4) | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | called by pindel, varscan2
- TMEM92 | c.413del p.P138Lfs*86 | Frame Shift Del (DEL) | VAF 62/194 reads (32%) | called by mutect2, pindel, varscan2
- TNNC1 | c.53dup p.N18Kfs*2 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- TUB | c.781del p.Q261Rfs*76 (on ENST00000299506 / NM_177972.3; = p.Q316Rfs*76 on NM_003320.4) | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- UBN2 | c.2995del p.L999Wfs*16 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- UNC5CL | c.511dup p.A171Gfs*50 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, varscan2
- VPS13A | c.6879+1del p.X2293_splice | Splice Site (DEL) | VAF 33/94 reads (35%) | called by mutect2, pindel, varscan2
- VPS9D1 | c.198del p.D67Tfs*6 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- WDFY3 | c.3179del p.L1060Cfs*41 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- ZNF484 | c.1356del p.K452Nfs*116 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- ABCB4 | c.3633T>G p.A1211= (on ENST00000265723 / NM_018849.3; = p.A1204= on NM_000443.4) | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV55934203; called by muse, mutect2, varscan2
- ACER2 | c.312T>G p.A104= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV61820642; called by muse, mutect2, varscan2
- ACKR1 | c.957G>T p.L319= | Silent (SNP) | VAF 129/308 reads (42%) | catalogued as COSV63672530; called by muse, mutect2, varscan2
- ACKR3 | c.138G>A p.T46= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs375172239; called by muse, mutect2, varscan2
- ADAMTS18 | c.2907A>C p.A969= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs140716153; called by muse, mutect2, varscan2
- ADGRB3 | c.3672T>C p.D1224= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs1233232158, COSV53240961, COSV53257342; called by muse, mutect2, varscan2
- ADRA1D | c.1668C>T p.C556= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1252063014, COSV65240584; called by muse, mutect2, varscan2
- AFF4 | c.1236A>G p.E412= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV54793751; called by muse, mutect2, varscan2
- ALDH3B1 | c.624C>T p.T208= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as COSV50288323; called by muse, mutect2, varscan2
- ALMS1 | c.4851C>T p.S1617= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV52507687; called by muse, mutect2, varscan2
- ANG | c.378C>T p.N126= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs778252755, COSV59011907; called by muse, mutect2, varscan2
- ANOS1 | c.633T>G p.S211= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV52918382; called by muse, varscan2
- APAF1 | c.3534C>A p.G1178= (on ENST00000551964 / NM_181861.2; = p.G1124= on NM_001160.3) | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV59663393; called by muse, mutect2, varscan2
- ARHGEF4 | c.1947G>A p.T649= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs752204879, COSV58120859; called by mutect2, varscan2
- ARID5A | c.1437A>C p.A479= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV62590948; called by muse, mutect2, varscan2
- ASB11 | c.594T>C p.T198= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as COSV60354891; called by muse, mutect2
- ATP13A3 | c.3090G>A p.Q1030= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs1405352144, COSV55463504; called by muse, mutect2, varscan2
- ATP2B3 | c.1368C>T p.R456= | Silent (SNP) | VAF 55/165 reads (33%) | catalogued as COSV54844492, COSV54849464; called by muse, mutect2, varscan2
- BNC2 | c.2202C>T p.G734= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs376030025; ClinVar: not provided; called by muse, mutect2, varscan2
- C8orf34 | c.921C>T p.G307= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV61376771; called by muse, mutect2, varscan2
- CACNA1G | c.3714G>A p.A1238= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs755158469, COSV61724570; called by muse, mutect2, varscan2
- CCN3 | c.453T>C p.P151= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99423517; called by muse, mutect2, varscan2
- CD109 | c.795G>A p.T265= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs542993766, COSV54645487; called by muse, mutect2, varscan2
- CDH10 | c.1041A>G p.K347= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV52577618, COSV52579065; called by muse, mutect2, varscan2
- CDH20 | c.2175C>T p.Y725= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs745687199, COSV53004618; called by muse, mutect2, varscan2
- CDK11A | c.1176C>T p.G392= (on ENST00000378633 / NM_001313896.2; = p.G389= on NM_024011.4) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs534390289, COSV62265119; called by muse, mutect2, varscan2
- CELA2B | c.777C>T p.N259= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as rs377364021; called by muse, mutect2, varscan2
- CENPF | c.8979G>A p.P2993= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as rs1284259966, COSV65273568; called by muse, mutect2, varscan2
- CHST9 | c.567C>T p.Y189= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as rs764768308, COSV52434670; called by muse, mutect2, varscan2
- CILK1 | c.1890C>T p.D630= (on ENST00000350082 / NM_001375397.1; = p.D623= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV63153950; called by muse, mutect2, varscan2
- CLEC4D | c.522C>T p.P174= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs757282550, COSV55228052, COSV55228675; called by muse, mutect2, varscan2
- CLSTN3 | c.198C>T p.C66= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs367854375; called by mutect2, varscan2
- CNTN4 | c.2922A>G p.P974= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs969438664, COSV61871379; called by muse, mutect2, varscan2
- CNTN5 | c.2856T>G p.A952= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV54301627; called by muse, mutect2, varscan2
- CNTNAP2 | c.340C>A p.R114= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100662536, COSV62150589; called by muse, mutect2, varscan2
- CRACD | c.2251C>T p.L751= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV51719316; called by muse, varscan2
- CSMD2 | c.9006A>G p.G3002= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV53902090; called by muse, mutect2, varscan2
- CTNNA3 | c.876T>C p.T292= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV65571453; called by muse, mutect2, varscan2
- CTR9 | c.1275T>C p.T425= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV63728375; called by muse, mutect2, varscan2
- CUL4B | c.2184A>G p.G728= | Silent (SNP) | VAF 86/193 reads (45%) | catalogued as rs751669743, COSV60686610; called by muse, varscan2
- DACH2 | c.849T>G p.A283= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV64166588; called by muse, mutect2, varscan2
- DCTN4 | c.1128C>T p.Y376= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs200339298, COSV69782924; called by muse, mutect2, varscan2
- DDX19A | c.337C>A p.R113= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV56359573; called by muse, mutect2, varscan2
- DNAJC16 | c.1551T>C p.A517= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs1362609112, COSV65448388; called by muse, mutect2, varscan2
- DRD3 | c.1032C>T p.P344= | Silent (SNP) | VAF 73/172 reads (42%) | catalogued as COSV55679793; called by muse, mutect2, varscan2
- DTD1 | c.456T>C p.T152= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV66278940; called by mutect2, varscan2
- DYNC1I2 | c.54G>T p.L18= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs924815512, COSV55525409; called by muse, mutect2, varscan2
- E2F2 | c.1215A>G p.P405= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs754726067, COSV62276399; called by mutect2, varscan2
- EFCAB14 | c.1254A>G p.P418= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs766796523, COSV64238712; called by muse, mutect2, varscan2
- ELOA | c.2235T>C p.P745= | Silent (SNP) | VAF 68/168 reads (40%) | catalogued as rs1441790200, COSV69309938; called by muse, mutect2, varscan2
- ENO3 | c.594C>A p.A198= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV52776983; called by muse, mutect2, varscan2
- EYA1 | c.1641A>G p.R547= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV58160649; called by muse, mutect2, varscan2
- FAT2 | c.9162G>T p.G3054= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV55817708; called by muse, mutect2, varscan2
- FAT4 | c.8394T>G p.T2798= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV58679974; called by muse, mutect2, varscan2
- FOXK1 | c.825C>T p.D275= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs781575882, COSV61065504, COSV61068503; called by muse, mutect2, varscan2
- FOXP1 | c.123G>A p.T41= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs201155996; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- FOXP2 | c.522A>G p.Q174= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs368614280; ClinVar: benign; called by muse, mutect2, varscan2
- FRG2 | c.492A>G p.L164= | Silent (SNP) | VAF 55/272 reads (20%) | called by muse, mutect2, varscan2
- FZD10 | c.357G>A p.P119= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs761092010, COSV57473162; called by muse, mutect2, varscan2
- GDF9 | c.1260A>G p.V420= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV51526078; called by muse, mutect2, varscan2
- GNAQ | c.1079A>G p.*360= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV54111449; called by muse, mutect2, varscan2
- HCN1 | c.1182C>T p.T394= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1261922847, COSV100302482, COSV57504508, COSV57532447; ClinVar: likely benign; called by muse, mutect2, varscan2
- HECTD1 | c.1344G>A p.R448= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV67945880; called by muse, mutect2, varscan2
- HIC2 | c.1530C>T p.C510= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs749751090, COSV68041980; called by muse, mutect2, varscan2
- HRNR | c.5556C>T p.S1852= | Silent (SNP) | VAF 61/434 reads (14%) | catalogued as rs758124976, COSV64256758; called by muse, mutect2, varscan2
- HYDIN | c.14772G>A p.T4924= | Silent (SNP) | VAF 172/464 reads (37%) | catalogued as rs756408083, COSV66637339; called by muse, mutect2, varscan2
- IBTK | c.183C>A p.S61= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV60392249; called by muse, mutect2, varscan2
- JMJD4 | c.1065C>T p.S355= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs781408815, COSV59917565; called by muse, mutect2, varscan2
- JSRP1 | c.12A>T p.T4= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV55558769; called by muse, varscan2
- KCNA6 | c.1365C>T p.P455= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV54974809; called by muse, mutect2, varscan2
- KMT2C | c.9351C>T p.G3117= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs1312967915, COSV51428892; called by muse, mutect2, varscan2
- KRT39 | c.45A>G p.P15= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as rs1355525206, COSV62917083; called by muse, mutect2, varscan2
- KRT6A | c.738G>T p.V246= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV58104680, COSV58107299; called by muse, mutect2, varscan2
- LAMA5 | c.5718C>A p.P1906= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99443007; called by muse, mutect2
- LEFTY2 | c.957G>A p.S319= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs756750444, COSV100832522, COSV64746735; called by muse, mutect2, varscan2
- LMX1B | c.783C>T p.R261= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs371560611; called by muse, mutect2
- LPCAT2 | c.978C>T p.C326= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV50894965; called by muse, mutect2, varscan2
- LRP4 | c.2205C>A p.A735= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1208643013, COSV66135289; called by muse, mutect2, varscan2
- LRRN2 | c.318G>A p.S106= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs996683512, COSV65783543; called by muse, mutect2, varscan2
- MAN1A1 | c.130C>T p.L44= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1389323371, COSV63782220; called by muse, mutect2, varscan2
- MAP3K2 | c.1677G>A p.P559= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs373785879; called by muse, mutect2, varscan2
- MAPK4 | c.283C>T p.L95= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV68541753; called by muse, mutect2, varscan2
- MCAM | c.330C>T p.D110= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs770425833, COSV50680034; called by muse, mutect2, varscan2
- MELTF | c.1356C>T p.Y452= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs376828332; called by muse, mutect2, varscan2
- MORC3 | c.420G>A p.A140= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as rs1225824139, COSV68688200; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1962A>G p.V654= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV54914385; called by muse, mutect2, varscan2
- MTRF1 | c.1149G>A p.E383= | Silent (SNP) | VAF 99/266 reads (37%) | catalogued as COSV65263203; called by muse, mutect2, varscan2
- MYLK2 | c.828C>T p.T276= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs370429139; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1H | c.1083A>G p.A361= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV60444732; called by muse, mutect2, varscan2
- NEBL | c.2949C>T p.N983= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs775709930, COSV65802454; called by muse, mutect2, varscan2
- NUP62 | c.552A>G p.A184= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV61311840; called by muse, mutect2, varscan2
- OPRL1 | c.1065C>T p.D355= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs367711919; called by muse, mutect2, varscan2
82 further variants in this file (0 protein-altering or splice-affecting, 63 silent, 19 other) are not listed here.
